Gene-level copy-number profile of tumor specimen HCM-BROD-0594-C43-06A from HCMI case HCM-BROD-0594-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.4 years (27,524 days).
Specimen HCM-BROD-0594-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f620e9b7-22c1-44c3-adbf-5f19d5533c50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0594-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/cc707618-7fb0-4f22-8c0d-4687ed4d2c93

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,320; copy number 2: 20,163; copy number 3: 13,810; copy number 4: 19,515; copy number 5: 2,498; copy number 6: 449; copy number 12: 26; copy number 13: 3; copy number 14: 16; copy number 17: 6; copy number 28: 16; copy number 34: 5; copy number 35: 3; copy number 36: 12; copy number 40: 3; copy number 54: 1; copy number 60: 7; copy number 62: 4; copy number 64: 11.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr3:141,324,213–141,471,902, 3 genes (within-gene range 0–2): ZBTB38, AC010184.1, KRT18P35.
- chr3:141,525,133–141,526,121, 1 gene (within-gene range 0–2): RASA2-IT1.
- chr4:9,459,255–9,460,244, 1 gene: OR7E86P.
- chr10:46,549,044–46,649,276, 5 genes (within-gene range 0–1): GPRIN2, SYT15, AL356056.2, AL356056.1, RN7SL248P.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr17:16,786,489–16,832,830, 9 genes (within-gene range 0–2): USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 113 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,829,747–129,496,788, 26 genes, copy number 12: Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1, Y_RNA, RNA5SP103, ISCA1P6, AC012451.1, AC068483.1, LINC01854, PPIAP65.
- chr3:32,730,635–33,869,707, 20 genes, copy number 34–64: CNOT10-AS1, RPL23AP43, TRIM71, CCR4, SEC13P1, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, SDAD1P3, AC112220.2, PDCD6IP.
- chr3:68,975,217–69,968,336, 14 genes, copy number 40–62: EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P.
- chr3:80,761,042–82,808,021, 16 genes, copy number 14: AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr10:42,149,310–43,267,065, 34 genes, copy number 17–36: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A.
- chr17:26,981,694–27,003,259, 3 genes, copy number 13: AC069061.1, AC069061.2, PDLIM1P3.

Autosomal genes at a single copy (total copy number 1): 1,218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
